Somatic mutation profile of tumor specimen MMRF_2201_1_BM_CD138pos (aliquot MMRF_2201_1_BM_CD138pos_T1_KHS5U_L08814) from MMRF case MMRF_2201, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.8 years (27,695 days).
Specimen MMRF_2201_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 073e98ef-7c1e-488e-ac2d-e108cf3e3e54.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2201_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2201_1_PB_Whole_C3_KHS5U_L08784; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cc48b1b-6c79-4f1a-ab07-647a022304b7

The open-access MAF lists 140 somatic variants for this specimen: 50 protein-altering or splice-affecting, 23 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 38, Silent 23, Intron 15, 5'Flank 6, 5'UTR 6, Splice Region 3, Frame Shift Del 3, RNA 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.2339G>A p.R780K | Missense Mutation (SNP) | VAF 12/68 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705570, COSV66707409; called by muse, mutect2, varscan2
- DIS3 | c.1462G>A p.D488N | Missense Mutation (SNP) | VAF 17/87 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705661, COSV66706270; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 23/116 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- CFAP206 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745368981, COSV51537161; called by muse, mutect2, varscan2
- COBL | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 78/186 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV104371568; called by muse, mutect2, varscan2
- COL6A3 | c.3274G>A p.V1092I | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.85); PolyPhen benign (0.005); catalogued as rs576798969, COSV55085649; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK7 | c.80A>G p.Y27C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.907); catalogued as rs771576993; called by muse, mutect2, varscan2
- DSCAM | c.3724G>A p.D1242N | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as rs770132126, COSV68020895; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.726); catalogued as rs1463579982; called by muse, mutect2, varscan2
- EBF1 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs200547458; called by muse, mutect2, varscan2
- ELAPOR1 | c.1041G>A p.E347= | Splice Region (SNP) | VAF 13/38 reads (34%) | catalogued as rs1229238176; called by muse, mutect2, varscan2
- FOXA2 | c.457C>G p.R153G (on ENST00000377115 / NM_153675.3; = p.R159G on NM_021784.5) | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs955822437, COSV65796227; called by muse, mutect2, varscan2
- FRMD4B | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780396995; called by muse, mutect2, varscan2
- KCNH7 | c.186del p.K62Nfs*51 | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | catalogued as COSV59807153; called by mutect2, pindel, varscan2
- NAV3 | c.2446G>C p.D816H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV99896853; called by muse, mutect2, varscan2
- PLCD3 | c.2069T>C p.I690T | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs368541443; called by muse, mutect2, varscan2
- PLOD3 | c.884C>T p.P295L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV99778370; called by muse, mutect2, varscan2
- SI | c.2515G>A p.D839N | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.03); catalogued as rs201944977, COSV52265311, COSV52286186, COSV52301725; called by muse, varscan2
- SLIT2 | c.3881G>A p.R1294H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as rs759513879; called by muse, mutect2, varscan2
- TACC2 | c.3364G>A p.E1122K | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs977241449; called by muse, mutect2, varscan2
- ABCA4 | c.4399T>A p.S1467T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- AKAP9 | c.1667G>A p.S556N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ARHGAP36 | c.320-6C>T | Splice Region (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- ASB7 | c.733T>C p.Y245H | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- BAHCC1 | c.2654G>A p.S885N | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- BMPR1B | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD163L1 | c.1945G>C p.D649H | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.972); called by muse, mutect2
- CD163L1 | c.1778C>A p.S593* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | called by muse, mutect2, varscan2
- CEL | c.380T>C p.I127T (on ENST00000673714; = p.I124T on NM_001807.6) | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DMKN | c.727_728del p.N243Lfs*19 | Frame Shift Del (DEL) | VAF 8/89 reads (9%) | called by mutect2, pindel
- FAT1 | c.12737C>A p.P4246Q | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GIMAP7 | c.765A>T p.L255F | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.034); called by mutect2, varscan2
- GLIPR1L2 | c.950T>G p.I317R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); called by muse, mutect2
- GPRIN3 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HYAL4 | c.199C>A p.L67I | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MFHAS1 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- MRC1 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NAP1L3 | c.1377T>A p.D459E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.446); called by muse, mutect2
- PARG | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PLD1 | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 62/135 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- POMGNT1 | c.1602C>T p.D534= | Splice Region (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- PRKDC | c.3764G>C p.C1255S | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RAI14 | c.1491A>T p.K497N | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- RNF150 | c.311C>A p.P104H | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- SLC25A31 | c.407G>A p.G136E | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPX | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2
- UNC80 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- YIPF5 | c.116A>G p.Y39C | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- ZNF451 | c.1411del p.T471Pfs*16 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- ZNF614 | c.446G>T p.R149I | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ADNP | c.1929A>G p.L643= | Silent (SNP) | VAF 9/183 reads (5%) | called by muse, mutect2
- ANKRD17 | c.2145T>C p.Y715= | Silent (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- ATP13A4 | c.657T>C p.S219= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs751485776; called by muse, mutect2, varscan2
- CALML3 | c.402C>T p.D134= | Silent (SNP) | VAF 32/101 reads (32%) | catalogued as COSV59449955; called by muse, mutect2, varscan2
- CNP | c.315G>A p.E105= | Silent (SNP) | VAF 9/152 reads (6%) | catalogued as COSV66367770; called by muse, mutect2
- COG6 | c.1875T>A p.G625= | Silent (SNP) | VAF 44/121 reads (36%) | called by muse, mutect2, varscan2
- COL4A6 | c.4971G>A p.V1657= | Silent (SNP) | VAF 32/60 reads (53%) | called by muse, mutect2, varscan2
- GRIN2A | c.1713A>T p.I571= | Silent (SNP) | VAF 48/111 reads (43%) | called by muse, mutect2, varscan2
- HMGB3 | c.348C>T p.P116= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs782232648, COSV57487099; called by muse, mutect2, varscan2
- HTR2C | c.1353T>G p.V451= | Silent (SNP) | VAF 36/110 reads (33%) | called by muse, varscan2
- IFNL2 | c.336C>T p.T112= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as rs777999084; called by muse, mutect2, varscan2
- LRBA | c.1782G>C p.L594= | Silent (SNP) | VAF 13/76 reads (17%) | called by muse, mutect2, varscan2
- NTN4 | c.1653C>T p.V551= | Silent (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- RYR2 | c.10413G>A p.K3471= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as rs1240803874, COSV63703882; called by muse, mutect2, varscan2
- SEMA4D | c.288A>G p.K96= | Silent (SNP) | VAF 29/61 reads (48%) | catalogued as rs963522180; called by muse, mutect2, varscan2
- SPDYC | c.6C>G p.L2= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs900166275; called by muse, mutect2, varscan2
- STT3A | c.777C>T p.F259= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as rs1370383958; called by muse, mutect2
- SUPT3H | c.115C>T p.L39= | Silent (SNP) | VAF 7/32 reads (22%) | called by muse, mutect2, varscan2
- TDP1 | c.708T>A p.A236= | Silent (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- UBE2Z | c.939C>G p.L313= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2, varscan2
- UNK | c.1668C>T p.S556= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as rs1216355430, COSV53146782; called by muse, mutect2, varscan2
- WASF3 | c.825C>T p.H275= | Silent (SNP) | VAF 46/205 reads (22%) | catalogued as rs374111218; called by muse, mutect2, varscan2
- Z83844.2 | c.513C>A p.A171= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV60930088; called by muse, mutect2, varscan2
- AC022415.2 | c.*2377C>T | 3'UTR (SNP) | VAF 74/231 reads (32%) | catalogued as rs1357745222; called by muse, mutect2, varscan2
- ANKIB1 | c.*2287del | 3'UTR (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- API5 | c.1222-213G>A | Intron (SNP) | VAF 3/13 reads (23%) | called by muse, mutect2
- ARL6IP6 | c.*1339G>A | 3'UTR (SNP) | VAF 4/27 reads (15%) | catalogued as rs912020670; called by muse, mutect2, varscan2
- ATP8B1 | c.*1156T>A | 3'UTR (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- BCL2L11 | c.*2490G>A | 3'UTR (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- BCL7A | chr12:122020969 C>G | 5'Flank (SNP) | VAF 38/94 reads (40%) | catalogued as COSV55849224, COSV55851032; called by muse, mutect2, varscan2
- BCL7A | chr12:122021448 ins ACTCTTT | 5'Flank (INS) | VAF 20/72 reads (28%) | called by mutect2, varscan2
- BDNF | c.*1067A>G | 3'UTR (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- BEND3 | c.*2848G>A | 3'UTR (SNP) | VAF 49/106 reads (46%) | catalogued as rs912663018; called by muse, varscan2
- C14orf39 | c.*173G>A | 3'UTR (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- CCDC62 | c.-29G>C | 5'UTR (SNP) | VAF 15/62 reads (24%) | called by muse, mutect2, varscan2
- CDH19 | c.*2911G>A | 3'UTR (SNP) | VAF 16/72 reads (22%) | catalogued as rs1237512773; called by muse, mutect2, varscan2
- CDS2 | c.*4097G>T | 3'UTR (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- CLK4 | c.*304C>T | 3'UTR (SNP) | VAF 13/78 reads (17%) | called by muse, mutect2, varscan2
- CLTC | c.*2486C>G | 3'UTR (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- CTDSP1 | c.378+14A>T | Intron (SNP) | VAF 41/130 reads (32%) | called by muse, mutect2, varscan2
- CUL3 | c.67-11854A>T | Intron (SNP) | VAF 9/19 reads (47%) | called by muse, mutect2
- DDX3X | c.-81T>C | 5'UTR (SNP) | VAF 8/28 reads (29%) | called by muse, mutect2, varscan2
- EGFEM1P | n.754dup | RNA (INS) | VAF 11/58 reads (19%) | catalogued as rs1033850231; called by mutect2, varscan2
- ELP3 | c.*407G>A | 3'UTR (SNP) | VAF 20/60 reads (33%) | catalogued as COSV99833867; called by muse, mutect2, varscan2
- EMX1 | c.*209C>G | 3'UTR (SNP) | VAF 7/73 reads (10%) | called by muse, mutect2
- FAM205BP | n.3156G>A | RNA (SNP) | VAF 41/94 reads (44%) | called by muse, mutect2, varscan2
- FAM227B | c.546+102T>C | Intron (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- FBXL13 | c.-100T>C | 5'UTR (SNP) | VAF 25/140 reads (18%) | called by muse, mutect2, varscan2
- FCHSD2 | c.*1600G>A | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- GLB1L3 | chr11:134275892 C>T | 5'Flank (SNP) | VAF 58/239 reads (24%) | catalogued as rs1297120504; called by muse, mutect2, varscan2
- GPIHBP1 | c.*1122G>C | 3'UTR (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- IL17A | c.*483A>T | 3'UTR (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- IL7R | c.*3010C>T | 3'UTR (SNP) | VAF 5/22 reads (23%) | catalogued as rs914556490; called by muse, mutect2, varscan2
- KDM2A | c.2932+22T>C | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- KIF1A | c.*160C>T | 3'UTR (SNP) | VAF 11/39 reads (28%) | catalogued as rs1047424971; called by muse, mutect2, varscan2
- KIF1B | c.2115+8064C>T | Intron (SNP) | VAF 5/50 reads (10%) | called by muse, mutect2, varscan2
- KLHL1 | c.*1044T>C | 3'UTR (SNP) | VAF 23/40 reads (58%) | called by muse, mutect2, varscan2
- LRP1B | c.*133T>A | 3'UTR (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2, varscan2
- MAGOHB | c.*77T>G | 3'UTR (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- MDGA2 | c.2752+1660A>G | Intron (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- MMP16 | c.*2216C>A | 3'UTR (SNP) | VAF 20/45 reads (44%) | called by muse, varscan2
- MTMR9 | c.*2763A>C | 3'UTR (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- NCR1 | c.70+46C>T | Intron (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- NEDD1 | c.-189T>C | 5'UTR (SNP) | VAF 33/117 reads (28%) | called by muse, mutect2, varscan2
- NOX4 | c.447+41T>A | Intron (SNP) | VAF 19/62 reads (31%) | called by muse, mutect2, varscan2
- NTRK3 | c.*16644G>A | 3'UTR (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- NTRK3 | c.*15721A>T | 3'UTR (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- OXTR | c.*2048G>C | 3'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- PCDHB8 | c.-210G>A | 5'UTR (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- PGAP4 | c.*2518G>A | 3'UTR (SNP) | VAF 29/61 reads (48%) | called by muse, mutect2, varscan2
- PLXDC2 | chr10:19816277 G>T | 5'Flank (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- PPP1R3B | chr8:9151750 G>C | 5'Flank (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- PTGDR2 | c.*1356C>T | 3'UTR (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- RAB27B | c.*1337G>A | 3'UTR (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2, varscan2
- RBMS3 | chr3:29281011 T>G | 5'Flank (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- RPH3A | c.*744A>C | 3'UTR (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.722-36471C>T | Intron (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- SFTPA2 | c.*196A>G | 3'UTR (SNP) | VAF 19/92 reads (21%) | called by muse, mutect2, varscan2
- SYMPK | c.2893+44G>C | Intron (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- TLE3 | c.190-189T>G | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- TMEM154 | c.*7043C>G | 3'UTR (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- TMEM65 | c.*1580T>C | 3'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- TNFAIP6 | c.*341T>A | 3'UTR (SNP) | VAF 10/31 reads (32%) | called by muse, mutect2, varscan2
- TRPV6 | c.1407-9C>A | Intron (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- UBE2QL1 | c.*2371G>A | 3'UTR (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- UBIAD1 | c.*511C>T | 3'UTR (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- XPO5 | c.3067-26G>T | Intron (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- YBX1 | c.167-160G>A | Intron (SNP) | VAF 21/56 reads (38%) | catalogued as rs1038754592; called by muse, mutect2, varscan2
- ZNF662 | c.*861T>A | 3'UTR (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- ZNF667 | c.-9G>A | 5'UTR (SNP) | VAF 88/185 reads (48%) | catalogued as COSV99410323; called by muse, mutect2, varscan2
